Somatic mutation profile of tumor specimen TARGET-40-PAUKXW-01A (aliquot TARGET-40-PAUKXW-01A-01D) from TARGET case TARGET-40-PAUKXW, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 15.8 years (5,781 days).
Specimen TARGET-40-PAUKXW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52e8c68d-f212-422f-8a1d-49c160b0fb29.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAUKXW-10A (Blood Derived Normal), aliquot TARGET-40-PAUKXW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32f1abcd-390d-41b2-913f-5495e611d650

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARMCX2 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRM7 | c.1260C>T p.H420= | Silent (SNP) | VAF 25/114 reads (22%) | catalogued as rs369533386, COSV100738210; called by muse, mutect2, varscan2
